Somatic mutation profile of tumor specimen ALCH-B1VZ-TTP1-A (aliquot ALCH-B1VZ-TTP1-A-1-0-D-A76N-36) from ALCHEMIST case ALCH-B1VZ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 45.8 years (16,740 days).
Specimen ALCH-B1VZ-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 46625ed4-4489-4c54-9465-5ae5e6c0a0c5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1VZ-NB1-A (Blood Derived Normal), aliquot ALCH-B1VZ-NB1-A-1-0-D-A76N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3db59d92-5adc-4b90-8117-c1e7d56a1fad

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 3, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAS | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 71/845 reads (8%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs121913495, CM158823, COSV55670349, COSV55671845; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 79/292 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ARHGAP21 | c.1569dup p.Q524Tfs*10 | Frame Shift Ins (INS) | VAF 12/125 reads (10%) | catalogued as rs1565032132; called by mutect2, pindel
- DTYMK | c.319G>A p.G107S | Missense Mutation (SNP) | VAF 19/215 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs140262226; called by muse, mutect2
- NLRP1 | c.1048G>C p.A350P | Missense Mutation (SNP) | VAF 11/135 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52569978; called by muse, mutect2
- RET | c.2945G>A p.R982H | Missense Mutation (SNP) | VAF 28/482 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.356); catalogued as rs368550200, COSV60699648; ClinVar: uncertain significance / likely benign; called by muse, mutect2
- SPON1 | c.2330G>A p.R777H | Missense Mutation (SNP) | VAF 16/229 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868925163, COSV59964340; called by muse, mutect2
- TRHDE | c.3001G>A p.E1001K | Missense Mutation (SNP) | VAF 9/155 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.097); catalogued as rs1219010746, COSV53836177; called by muse, mutect2
- KLHL18 | c.296G>A p.G99D | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ONECUT3 | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.91); PolyPhen benign (0.067); called by muse, varscan2
- HERC2 | c.4254G>A p.Q1418= | Silent (SNP) | VAF 20/296 reads (7%) | called by muse, mutect2
- PRSS53 | c.1590C>T p.F530= | Silent (SNP) | VAF 13/189 reads (7%) | catalogued as rs760220212, COSV54923559; called by muse, mutect2
- RNF14 | c.975C>T p.T325= | Silent (SNP) | VAF 28/537 reads (5%) | called by muse, mutect2
- SPATA31C1 | n.3036G>A | RNA (SNP) | VAF 30/408 reads (7%) | catalogued as rs529896552; called by muse, mutect2
